Surgical pathology report (de-identified scan), TCGA case TCGA-29-1699, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Duke, specimen TCGA-29-1699-01A (Primary Tumor).

[page 1 of 3]
[REDACTED]

[REDACTED]

Surg Path

CLINICAL HISTORY:

Malignant neoplasm ovary

TCGA-29-1699

GROSS EXAMINATION:

A. "Omentum". Received fresh for frozen section is a 25 x 9 x 2.5 cm portion of omentum that is caked with tan-white tumor nodules. The frozen section remnant AF1 is submitted as A1 and additional representative section is submitted as block A2.

B. "Left tube and ovary". Received is a 159 gram, 8.5 x 7.5 x 4.5 cm cystic ovarian remnant with tan-white tumor mass. Sectioning the mass shows multiple blood and fluid filled cysts and large areas of necrosis. An ovarian remnant is hard to appreciate grossly. The 7.5 x 0.8 cm segment of fimbriated fallopian tube is studded with tumor.

BLOCK SUMMARY:

- B1-2- ovary and tumor
- B3- solid area of edge of cyst
- B4- representative of fallopian tube

C. "Right tube and ovary". Received in formalin is a 144.8 gram, 8 x 6 x 5.5 cm multicystic ovary with a 5.5 x 4.5 x 2.5 cm tan-white necrotic tumor mass emerging from its external surface. Cross section of the ovary and mass shows mostly solid and white necrotic tumor with multiple large and clear fluid filled cystic spaces. Ovarian remnant is difficult to grossly identify, however, an 8 cm length of fallopian tube studded with tumor is identified.

BLOCK SUMMARY:

- C1-2- tumor in its relation to external surface of specimen
- C3- representative of tumor
- C4- fallopian tube

D. "Tumor". Received is a 10 x 7.5 x 6.9 cm mass of tan-white tumor that includes a thin walled cyst reminiscent of cystic ovary. Sectioning of the main tumor mass shows a fibrotic white whorled cut surface on the edge of the tumor measuring 3 x 1.5 x 0.6 cm, reminiscent of ovarian tissue.

BLOCK SUMMARY:

- D1- representative of cyst
- D2-3- representative of fibrotic tumor mass
- D4- potential ovarian remnant

E. "Uterus". Received is a 286 gram, 9 x 7 x 6.5 cm uterus that shows a roughened serosal surface suspicious for tumor studding. Within the uterus the endometrium is distended by a 5.5 x 4.5 x 4.0 cm leiomyoma. The cervix is not present in this specimen.

BLOCK SUMMARY:

- E1-2- leiomyoma
- E3- representatives of roughened serosal surface
- E4- representative of endometrium

F. "Bladder peritoneum". Received is an 11 x 5 x 1.9 cm segment of fibrofatty tissue studded with multiple tumor nodules. A representative section is

[REDACTED]

[page 2 of 3]
placed in F1.

G. "Cecum and ileum". Received is a 24 x 7 cm length of bowel that includes a 6 cm length of colon. No appendix is grossly identified. The mucosal surface is grossly unremarkable. The serosal surface, however, shows numerous tumor nodules on the surface.

BLOCK SUMMARY:

- G1- proximal margin (ileum)
- G2- distal margin (large bowel)
- G3- representative of serosal tumor nodules

TCGA-29-1699

H. "Rectosigmoid and cervix". Received is an 18 x 4 x 1.5 cm segment of rectosigmoid that shows a 2.5 cm long stricture. Overlying the stricture is a 2.5 x 1.2 x 1.0 cm tumor nodule involving the serosa. Otherwise the mucosa of the rectosigmoid is grossly unremarkable. Also attached to this specimen is a 3.3 x 3.0 x 2.0 cm cervix that is grossly unremarkable.

BLOCK SUMMARY:

- H1- distal margin of rectosigmoid
- H2- proximal margin of rectosigmoid
- H3- stricture and tumor
- H4- representative of cervix

I. "Right external iliac node". Received is a 4.2 x 3.0 x 1.6 cm aggregate of three grossly positive lymph nodes. Representative sections of two nodes are submitted in block I1 and I2 and the third lymph node is submitted entirely as block I3.

J. "Rectal margin". Received is a 7 cm in diameter mushroom shaped steel surgical device with 3 x 0.4 x 0.2 cm segment of mucosa is removed from the surgical device and submitted as J1.

INTRA OPERATIVE CONSULTATION:

A. "Omentum": AF1-poorly differentiated carcinoma

MICROSCOPIC EXAMINATION:

Microscopic examination is performed.

DIAGNOSIS:

A. "OMENTUM" (OMENTECTOMY):

METASTATIC PAPILLARY SEROUS CARCINOMA (>2 CM).

B. "LEFT FALLOPIAN TUBE AND OVARY" (SALPINGO-OOPHORECTOMY):

OVARY WITH POORLY DIFFERENTIATED PAPILLARY SEROUS CARCINOMA

FIGO GRADE: 3 OF 3.

TUMOR SIZE: 8.5 X 7.5 X 4.5 CM.

SURFACE INVOLVEMENT: PRESENT.

FALLOPIAN TUBE: POSITIVE FOR CARCINOMA.

C. "RIGHT TUBE AND OVARY" (SALPINGO-OOPHORECTOMY):

OVARY WITH POORLY DIFFERENTIATED PAPILLARY SEROUS CARCINOMA

FIGO GRADE: 3 OF 3.

TUMOR SIZE: 8 X 6 X 5.5 CM.

SURFACE INVOLVEMENT: PRESENT.

FALLOPIAN TUBE: POSITIVE FOR CARCINOMA.

[page 3 of 3]
D. "TUMOR" (EXCISION):

PAPILLARY SEROUS CARCINOMA, AND PORTION OF FIBROMA.

E. "UTERUS" (HYSTERECTOMY):

UTERUS, 286 GRAMS:

SEROSA: METASTATIC SEROUS CARCINOMA

ENDOMETRIUM: PROLIFERATIVE, WITH ENDOMETRIAL POLYP.

MYOMETRIUM: LEIOMYOMA (5.5 CM).

CERVIX: SUBMITTED SEPARATELY.

TCGA-29-1699

F. "BLADDER PERITONEUM":

METASTATIC PAPILLARY SEROUS CARCINOMA.

G. "CECUM AND ILEUM" (RESECTION):

COLON AND SMALL BOWEL WITH MULTIPLE METASTASES OF PAPILLARY SEROUS CARCINOMA.

H. "RECTOSIGMOID COLON, AND CERVIX" (EXCISION):

SEGMENT OF COLON WITH MULTIPLE METASTASES OF PAPILLARY SEROUS CARCINOMA,
WITH STRICTURE OF COLON.

CERVIX IS FREE OF TUMOR.

I. "RIGHT EXTERNAL ILIAC NODE":

THREE LYMPH NODES WITH METASTATIC PAPILLARY SEROUS CARCINOMA (3/3).

J. "RECTAL MARGIN" (BIOPSY):

SEGMENT OF COLON, FREE OF TUMOR.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 1b69b6ff-3a3e-4df7-a06e-b871ebb658b7 (TCGA-29-1699.9E2CF2F9-C45C-4702-8B6F-565C59730036.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).